Somatic mutation profile of tumor specimen MMRF_2794_1_BM_CD138pos (aliquot MMRF_2794_1_BM_CD138pos_T1_KHS5U_L15735) from MMRF case MMRF_2794, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow.
Specimen MMRF_2794_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e99df4f7-0861-4659-abc4-3aef1930dfa3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2794_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2794_1_PB_WBC_C3_KHS5U_L15779; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/48e7ac98-fb98-4e8a-9944-5c08081211b3

The open-access MAF lists 388 somatic variants for this specimen: 138 protein-altering or splice-affecting, 49 silent, 201 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 121, 3'UTR 111, Silent 49, Intron 48, 5'UTR 21, Nonsense Mutation 14, 5'Flank 8, 3'Flank 7, RNA 6, Frame Shift Del 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AADAC | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 87/276 reads (32%) | SIFT tolerated (0.47); PolyPhen benign (0.057); catalogued as rs79925965; called by muse, mutect2, varscan2
- AMER1 | c.737C>T p.S246F | Missense Mutation (SNP) | VAF 53/203 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as COSV57668599, COSV57670832; called by muse, mutect2, varscan2
- ARMC3 | c.865C>T p.P289S | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.774); catalogued as rs1251243013, COSV99957316; called by muse, mutect2, varscan2
- ATP10A | c.1528G>A p.E510K | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.608); catalogued as rs559836413; called by muse, mutect2, varscan2
- ATP11A | c.1373C>T p.S458L | Missense Mutation (SNP) | VAF 51/114 reads (45%) | SIFT tolerated (0.39); PolyPhen benign (0.063); catalogued as rs747653243, COSV52117024; called by muse, mutect2, varscan2
- ATP13A3 | c.3184G>A p.E1062K | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.46); PolyPhen benign (0.006); catalogued as rs531855588, COSV55462596; called by muse, mutect2, varscan2
- CCN3 | c.982A>G p.I328V | Missense Mutation (SNP) | VAF 95/190 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.306); catalogued as COSV52383722; called by muse, mutect2, varscan2
- CNTN5 | c.2050G>A p.E684K | Missense Mutation (SNP) | VAF 41/93 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as rs200579368, COSV54326826; called by mutect2, varscan2
- COL15A1 | c.3526T>A p.L1176I | Missense Mutation (SNP) | VAF 46/94 reads (49%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.651); catalogued as COSV66643060; called by muse, mutect2, varscan2
- COL4A2 | c.4954G>A p.A1652T | Missense Mutation (SNP) | VAF 43/86 reads (50%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.942); catalogued as rs763103910, COSV100847246, COSV64633658; called by muse, mutect2, varscan2
- COL8A2 | c.427C>T p.R143W | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as rs749319879; called by muse, mutect2, varscan2
- CPSF1 | c.2188G>A p.E730K | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT tolerated (0.46); PolyPhen benign (0.026); catalogued as rs1554864545, COSV58236021; called by muse, mutect2, varscan2
- CPSF6 | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.135); catalogued as COSV99879015; called by muse, mutect2
- DHX37 | c.1678G>A p.E560K | Missense Mutation (SNP) | VAF 49/109 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.321); catalogued as COSV58137657; called by muse, mutect2, varscan2
- ERBB3 | c.1831C>T p.R611W | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs373609369; called by muse, mutect2, varscan2
- FOXL2NB | c.98C>T p.S33L | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.973); catalogued as rs1264559033; called by muse, mutect2, varscan2
- GPR22 | c.764G>C p.R255T | Missense Mutation (SNP) | VAF 53/196 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.239); catalogued as rs1476229470; called by muse, mutect2, varscan2
- GPRIN2 | c.1363G>A p.A455T | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.61); PolyPhen benign (0.03); catalogued as rs782136338; called by muse, mutect2, varscan2
- HERC1 | c.8376G>C p.M2792I | Missense Mutation (SNP) | VAF 48/176 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV71250243; called by muse, mutect2, varscan2
- HYDIN | c.3007G>A p.D1003N | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV100377378, COSV58570721; called by muse, mutect2, varscan2
- IGKV2-30 | c.232A>T p.N78Y | Missense Mutation (SNP) | VAF 87/198 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs182126464; called by muse, mutect2, varscan2
- INHBA | c.1094C>T p.S365L | Missense Mutation (SNP) | VAF 60/218 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.414); catalogued as COSV54226454; called by muse, mutect2, varscan2
- KCNJ2 | c.513C>G p.I171M | Missense Mutation (SNP) | VAF 42/80 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV54660781, COSV54662151; called by muse, mutect2, varscan2
- KCNK10 | c.862G>A p.A288T | Missense Mutation (SNP) | VAF 56/148 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as rs745846560, COSV56648453; called by muse, mutect2, varscan2
- KLKB1 | c.1447G>T p.D483Y | Missense Mutation (SNP) | VAF 64/130 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99249816; called by muse, mutect2, varscan2
- LCORL | c.1556G>A p.R519H | Missense Mutation (SNP) | VAF 105/199 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV58837949; called by muse, mutect2, varscan2
- MAF | c.908A>G p.Q303R | Missense Mutation (SNP) | VAF 76/221 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.954); catalogued as CM144633; called by muse, varscan2
- MAP3K2 | c.1057C>G p.P353A | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.26); catalogued as rs1299732815, COSV61293931; called by muse, mutect2, varscan2
- MPHOSPH9 | c.679G>T p.G227* | Nonsense Mutation (SNP) | VAF 74/170 reads (44%) | catalogued as COSV56625578; called by muse, varscan2
- MTUS2 | c.1360G>C p.E454Q | Missense Mutation (SNP) | VAF 42/84 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.177); catalogued as COSV70922091; called by muse, mutect2, varscan2
- NCOR1 | c.3022C>T p.Q1008* | Nonsense Mutation (SNP) | VAF 39/102 reads (38%) | catalogued as COSV51974206; called by muse, mutect2, varscan2
- NKAIN2 | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs142309299; called by muse, varscan2
- NPNT | c.703C>T p.R235C | Missense Mutation (SNP) | VAF 64/129 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.601); catalogued as rs1343274076; called by muse, mutect2, varscan2
- NYAP1 | c.1984G>A p.E662K | Missense Mutation (SNP) | VAF 50/149 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.464); catalogued as rs367909423; called by muse, mutect2, varscan2
- OR14A16 | c.135G>A p.M45I | Missense Mutation (SNP) | VAF 67/208 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV62927592; called by muse, mutect2, varscan2
- PCDHB10 | c.1072G>C p.E358Q | Missense Mutation (SNP) | VAF 88/177 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs782383577; called by muse, mutect2, varscan2
- PDZD2 | c.7880G>A p.R2627K | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56852318; called by muse, mutect2, varscan2
- PIK3R3 | c.433C>G p.L145V | Missense Mutation (SNP) | VAF 66/184 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as COSV53111422; called by muse, mutect2, varscan2
- PNLIPRP3 | c.352T>G p.C118G | Missense Mutation (SNP) | VAF 90/162 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs1475024225; called by muse, varscan2
- PRIM2 | c.79C>T p.Q27* | Nonsense Mutation (SNP) | VAF 46/95 reads (48%) | catalogued as COSV51424604; called by muse, mutect2, varscan2
- PRSS35 | c.363G>C p.K121N | Missense Mutation (SNP) | VAF 74/178 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as COSV63801197; called by muse, mutect2, varscan2
- RIOK2 | c.1159G>A p.D387N | Missense Mutation (SNP) | VAF 8/169 reads (5%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV51615381; called by muse, mutect2
- RTL8C | c.181G>C p.D61H | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99924347; called by muse, mutect2, varscan2
- RYR2 | c.631C>T p.L211F | Missense Mutation (SNP) | VAF 37/125 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV63718327; called by muse, mutect2, varscan2
- SART1 | c.1388C>T p.S463L | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.241); catalogued as rs753596635; called by muse, mutect2, varscan2
- SLC6A14 | c.1127C>G p.S376C | Missense Mutation (SNP) | VAF 42/146 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.905); catalogued as COSV64149204; called by muse, mutect2, varscan2
- SLIT2 | c.673C>T p.R225C | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs767628989, COSV56567630; called by muse, mutect2, varscan2
- SOGA3 | c.2266G>A p.D756N | Missense Mutation (SNP) | VAF 55/133 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100846897; called by muse, mutect2, varscan2
- SOS2 | c.1300G>C p.D434H | Missense Mutation (SNP) | VAF 62/126 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV53572054, COSV99365202; called by muse, mutect2, varscan2
- SOX18 | c.866C>T p.T289M | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.15); PolyPhen benign (0.213); catalogued as rs1221934046; called by muse, mutect2, varscan2
- SPAG4 | c.149G>A p.R50K | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.142); catalogued as COSV100958303; called by muse, mutect2, varscan2
- TBC1D22A | c.707C>T p.S236L | Missense Mutation (SNP) | VAF 39/79 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.021); catalogued as COSV61447922; called by muse, mutect2, varscan2
- TNXB | c.4288G>A p.E1430K (on ENST00000647633; = p.E1183K on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.784); catalogued as rs781061300, COSV100926391; called by muse, mutect2, varscan2
- UNC13C | c.5342C>T p.S1781L | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.251); catalogued as COSV52912221; called by muse, mutect2, varscan2
- WDR64 | c.3170G>A p.R1057Q | Missense Mutation (SNP) | VAF 58/225 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs755961052, COSV63796175; called by muse, mutect2, varscan2
- ZKSCAN8 | c.1036G>A p.G346R | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57637345; called by muse, mutect2
- ZNF471 | c.791G>A p.C264Y | Missense Mutation (SNP) | VAF 86/137 reads (63%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs533651245; called by muse, mutect2, varscan2
- ZNF648 | c.1429C>T p.P477S | Missense Mutation (SNP) | VAF 54/195 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs998227572, COSV60571043; called by muse, mutect2, varscan2
- ABCC4 | c.2350C>G p.L784V | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- AC018630.4 | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 56/110 reads (51%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- ACSM6 | c.532G>C p.D178H | Missense Mutation (SNP) | VAF 50/106 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); called by muse, varscan2
- ADD3 | c.234G>C p.Q78H | Missense Mutation (SNP) | VAF 11/214 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- AFTPH | c.1187del p.P396Qfs*15 | Frame Shift Del (DEL) | VAF 84/188 reads (45%) | called by mutect2, varscan2
- AHRR | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- ALDOA | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 52/135 reads (39%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ANKRD13A | c.1352C>T p.S451F | Missense Mutation (SNP) | VAF 16/179 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.694); called by muse, mutect2
- ARHGEF11 | c.4216G>A p.D1406N | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); called by muse, mutect2
- BMT2 | c.882G>C p.K294N | Missense Mutation (SNP) | VAF 99/346 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- C11orf91 | c.199C>T p.Q67* | Nonsense Mutation (SNP) | VAF 9/20 reads (45%) | called by muse, mutect2
- C2CD2L | c.1732C>T p.P578S | Missense Mutation (SNP) | VAF 99/242 reads (41%) | SIFT tolerated (0.67); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CASKIN1 | c.2026G>T p.E676* | Nonsense Mutation (SNP) | VAF 36/77 reads (47%) | called by muse, mutect2, varscan2
- CBLB | c.529G>A p.D177N | Missense Mutation (SNP) | VAF 75/244 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- CCDC150 | c.1599_1601del p.Q534del | In Frame Del (DEL) | VAF 42/112 reads (38%) | called by mutect2, varscan2
- CD40LG | c.136C>T p.L46F | Missense Mutation (SNP) | VAF 72/229 reads (31%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.538); called by muse, mutect2, varscan2
- CHERP | c.2438C>T p.S813L | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- COL10A1 | c.1697G>T p.G566V | Missense Mutation (SNP) | VAF 77/158 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- COL7A1 | c.1174G>A p.E392K | Missense Mutation (SNP) | VAF 75/226 reads (33%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- COPA | c.343C>T p.Q115* | Nonsense Mutation (SNP) | VAF 92/330 reads (28%) | called by muse, mutect2
- CREB5 | c.1298A>T p.Q433L (on ENST00000357727 / NM_182898.4; = p.Q426L on NM_004904.3) | Missense Mutation (SNP) | VAF 51/153 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- CUBN | c.5686G>C p.E1896Q | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- CYP3A7-CYP3A51P | c.1596C>G p.I532M | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DUSP3 | c.94G>T p.E32* | Nonsense Mutation (SNP) | VAF 14/48 reads (29%) | called by muse, varscan2
- FHDC1 | c.1435G>C p.E479Q | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- FSIP2 | c.15205C>T p.Q5069* | Nonsense Mutation (SNP) | VAF 48/92 reads (52%) | called by muse, mutect2, varscan2
- GNB5 | c.184G>A p.E62K (on ENST00000261837 / NM_016194.4; = p.E20K on NM_006578.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GPR22 | c.204G>A p.M68I | Missense Mutation (SNP) | VAF 84/279 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.014); called by muse, varscan2
- GSE1 | c.1540C>T p.Q514* | Nonsense Mutation (SNP) | VAF 23/55 reads (42%) | called by muse, mutect2, varscan2
- HERC1 | c.10067C>T p.S3356L | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HRG | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- IGHV2-70 | chr14:106770575 TGGTA>GAGTT | Missense Mutation (ONP) | VAF 3/29 reads (10%) | called by pindel, varscan2*
- INSRR | c.2570G>T p.G857V | Missense Mutation (SNP) | VAF 53/166 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- INSYN2B | c.205C>G p.Q69E | Missense Mutation (SNP) | VAF 68/130 reads (52%) | SIFT tolerated (0.64); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- KANSL1L | c.802C>T p.Q268* | Nonsense Mutation (SNP) | VAF 86/187 reads (46%) | called by muse, mutect2, varscan2
- KLK5 | c.586C>T p.P196S | Missense Mutation (SNP) | VAF 46/125 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- KMT2B | c.6404C>G p.S2135* | Nonsense Mutation (SNP) | VAF 36/118 reads (31%) | called by muse, mutect2, varscan2
- LAG3 | c.1375C>T p.L459F | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- LRP1B | c.10498G>A p.D3500N | Missense Mutation (SNP) | VAF 58/111 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAF | c.250C>G p.Q84E | Missense Mutation (SNP) | VAF 57/139 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- MFNG | c.414C>G p.F138L | Missense Mutation (SNP) | VAF 93/268 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.475); called by muse, mutect2, varscan2
- MGAT4C | c.1222C>T p.H408Y | Missense Mutation (SNP) | VAF 52/114 reads (46%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MPC1L | c.400C>A p.Q134K | Missense Mutation (SNP) | VAF 57/102 reads (56%) | SIFT tolerated, low confidence (0.63); called by muse, mutect2, varscan2
- MRGPRX1 | c.189C>G p.I63M | Missense Mutation (SNP) | VAF 42/140 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- MYOM1 | c.468A>C p.E156D | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- NEO1 | c.790C>T p.Q264* | Nonsense Mutation (SNP) | VAF 71/246 reads (29%) | called by muse, mutect2, varscan2
- NKD1 | c.1078C>T p.H360Y | Missense Mutation (SNP) | VAF 78/156 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- NRROS | c.353C>G p.S118* | Nonsense Mutation (SNP) | VAF 40/150 reads (27%) | called by muse, mutect2, varscan2
- NXNL1 | c.352G>C p.E118Q | Missense Mutation (SNP) | VAF 61/223 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- NXPE4 | c.1319G>C p.R440T (on ENST00000375478 / NM_001077639.2; = p.R156T on NM_017678.3) | Missense Mutation (SNP) | VAF 70/179 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OPHN1 | c.889A>C p.T297P | Missense Mutation (SNP) | VAF 74/244 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- PCNT | c.7049G>A p.R2350K | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- PCSK6 | c.939G>C p.K313N | Missense Mutation (SNP) | VAF 71/219 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- PEX6 | c.1096G>C p.E366Q | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- PITPNA | c.309G>A p.M103I | Missense Mutation (SNP) | VAF 7/150 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); called by muse, mutect2
- PLXND1 | c.4627G>A p.E1543K | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- POLR2I | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- PRPF38B | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 50/125 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PTTG1 | c.353T>G p.F118C | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SERINC5 | c.5C>G p.S2* | Nonsense Mutation (SNP) | VAF 13/28 reads (46%) | called by muse, mutect2, varscan2
- SH3TC1 | c.6G>C p.E2D | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- SIPA1L3 | c.1561G>A p.E521K | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- SMG7 | c.3145G>A p.D1049N | Missense Mutation (SNP) | VAF 63/179 reads (35%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SPG11 | c.4596G>C p.K1532N | Missense Mutation (SNP) | VAF 57/195 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- STIMATE | c.624G>C p.L208F | Missense Mutation (SNP) | VAF 70/225 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- TAS2R8 | c.74G>A p.G25E | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- TENT5C | c.886T>C p.F296L | Missense Mutation (SNP) | VAF 61/68 reads (90%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- TMC5 | c.2590G>A p.D864N (on ENST00000396229 / NM_001105248.1; = p.D618N on NM_024780.5) | Missense Mutation (SNP) | VAF 50/117 reads (43%) | SIFT tolerated (0.5); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TMED4 | c.604C>G p.Q202E | Missense Mutation (SNP) | VAF 44/152 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- TMEM165 | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 67/120 reads (56%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.023); called by muse, varscan2
- TNFAIP8L1 | c.21G>C p.K7N | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- TNFRSF17 | c.485_486del p.N162Rfs*22 | Frame Shift Del (DEL) | VAF 41/99 reads (41%) | called by mutect2, pindel, varscan2
- TOMM6 | c.85C>T p.R29W | Missense Mutation (SNP) | VAF 61/151 reads (40%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- TPBGL | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- TRAPPC10 | c.1363G>A p.E455K | Missense Mutation (SNP) | VAF 49/160 reads (31%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.626); called by muse, mutect2, varscan2
- VWF | c.2753C>T p.S918L | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- WWTR1 | c.899T>G p.L300R | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- ZFHX2 | c.3673G>A p.D1225N | Missense Mutation (SNP) | VAF 82/191 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- ZFX | c.859C>A p.Q287K | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- ZNF701 | c.124G>C p.E42Q | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAMTS18 | c.2319C>T p.G773= | Silent (SNP) | VAF 50/102 reads (49%) | catalogued as rs150218700, COSV99271671; called by muse, mutect2, varscan2
- ADGRD2 | c.441C>T p.A147= | Silent (SNP) | VAF 22/43 reads (51%) | catalogued as rs868781107; called by muse, mutect2, varscan2
- ATP10D | c.2997C>T p.I999= | Silent (SNP) | VAF 49/123 reads (40%) | called by muse, mutect2, varscan2
- BCAM | c.1713G>A p.V571= | Silent (SNP) | VAF 60/150 reads (40%) | called by muse, mutect2, varscan2
- CACNA1F | c.1407C>T p.S469= | Silent (SNP) | VAF 47/140 reads (34%) | catalogued as rs1557109962; called by muse, mutect2, varscan2
- CARMIL2 | c.2490C>G p.S830= | Silent (SNP) | VAF 33/80 reads (41%) | called by muse, mutect2, varscan2
- CDH26 | c.1407C>T p.I469= | Silent (SNP) | VAF 60/130 reads (46%) | catalogued as rs765403675; called by muse, mutect2, varscan2
- CFAP94 | c.1683C>T p.F561= (on ENST00000320267 / NM_001352064.2; = p.F567= on NM_018272.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/35 reads (49%) | called by muse, mutect2, varscan2
- CHD8 | c.4701G>A p.K1567= (on ENST00000646647 / NM_001170629.2; = p.K1288= on NM_020920.4) | Silent (SNP) | VAF 46/121 reads (38%) | called by muse, mutect2, varscan2
- CHODL | c.60C>T p.F20= | Silent (SNP) | VAF 15/55 reads (27%) | called by muse, mutect2, varscan2
- CLCF1 | c.84C>G p.L28= | Silent (SNP) | VAF 29/79 reads (37%) | called by muse, mutect2, varscan2
- CNP | c.156C>A p.L52= | Silent (SNP) | VAF 103/207 reads (50%) | called by muse, mutect2, varscan2
- CX3CR1 | c.1056G>A p.L352= | Silent (SNP) | VAF 19/55 reads (35%) | called by muse, mutect2, varscan2
- DSG2 | c.1899G>A p.L633= | Silent (SNP) | VAF 6/143 reads (4%) | catalogued as rs867652392; called by muse, mutect2
- DSP | c.987G>A p.L329= | Silent (SNP) | VAF 52/152 reads (34%) | catalogued as rs564435126; ClinVar: likely benign; called by muse, mutect2, varscan2
- DUS1L | c.912G>A p.V304= | Silent (SNP) | VAF 4/75 reads (5%) | called by muse, mutect2
- EGLN1 | c.156G>A p.K52= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as rs766365190; called by muse, mutect2, varscan2
- FAM120A | c.1701G>A p.L567= | Silent (SNP) | VAF 44/92 reads (48%) | catalogued as rs765271651; called by muse, mutect2, varscan2
- HECTD4 | c.1899C>G p.V633= | Silent (SNP) | VAF 57/143 reads (40%) | called by muse, mutect2, varscan2
- IGHV2-70 | c.246A>C p.T82= | Silent (SNP) | VAF 46/50 reads (92%) | catalogued as rs367734033; called by muse, mutect2, varscan2
- KALRN | c.1203G>A p.K401= | Silent (SNP) | VAF 57/237 reads (24%) | catalogued as COSV53754058; called by muse, mutect2, varscan2
- KCNH7 | c.3201C>T p.V1067= | Silent (SNP) | VAF 25/55 reads (45%) | catalogued as rs767809489, COSV59812486; called by muse, mutect2, varscan2
- LRRC26 | c.804C>G p.L268= | Silent (SNP) | VAF 27/52 reads (52%) | catalogued as rs376111343; called by muse, mutect2, varscan2
- LRRC27 | c.819G>A p.V273= | Silent (SNP) | VAF 68/164 reads (41%) | catalogued as rs562416574; called by muse, mutect2, varscan2
- LRRIQ4 | c.303G>A p.L101= | Silent (SNP) | VAF 90/288 reads (31%) | called by muse, mutect2, varscan2
- MAF | c.448T>C p.L150= | Silent (SNP) | VAF 20/40 reads (50%) | called by muse, varscan2
- MAF | c.27C>T p.N9= | Silent (SNP) | VAF 25/83 reads (30%) | called by muse, mutect2, varscan2
- MLH3 | c.1455G>A p.E485= | Silent (SNP) | VAF 57/129 reads (44%) | catalogued as rs571554175; called by muse, mutect2, varscan2
- MN1 | c.1680G>A p.Q560= | Silent (SNP) | VAF 42/92 reads (46%) | called by muse, mutect2, varscan2
- MRGPRX1 | c.372C>A p.V124= | Silent (SNP) | VAF 43/153 reads (28%) | called by muse, mutect2, varscan2
- NR1H2 | c.825C>T p.I275= | Silent (SNP) | VAF 24/87 reads (28%) | catalogued as COSV53800125; called by muse, mutect2, varscan2
- ORAI1 | c.711C>T p.I237= | Silent (SNP) | VAF 81/155 reads (52%) | catalogued as rs781889490; called by muse, mutect2, varscan2
- PCYT1B | c.645T>G p.V215= | Silent (SNP) | VAF 86/141 reads (61%) | catalogued as COSV63263981; called by muse, mutect2, varscan2
- PDCD6 | c.483G>A p.L161= | Silent (SNP) | VAF 36/90 reads (40%) | called by muse, mutect2, varscan2
- PHF12 | c.1806G>A p.V602= | Silent (SNP) | VAF 18/105 reads (17%) | catalogued as COSV52020925; called by muse, mutect2, varscan2
- PIGW | c.1050C>T p.L350= | Silent (SNP) | VAF 48/106 reads (45%) | called by muse, mutect2, varscan2
- PLEKHA5 | c.2607G>A p.L869= | Silent (SNP) | VAF 79/148 reads (53%) | called by muse, mutect2, varscan2
- PPP1R3F | c.2289G>A p.L763= | Silent (SNP) | VAF 85/251 reads (34%) | called by muse, mutect2, varscan2
- RABGAP1 | c.3209G>A p.*1070= | Silent (SNP) | VAF 27/73 reads (37%) | catalogued as COSV65379640; called by muse, mutect2, varscan2
- RELN | c.7431C>T p.I2477= | Silent (SNP) | VAF 103/181 reads (57%) | catalogued as rs775529885; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RELN | c.4482G>A p.R1494= | Silent (SNP) | VAF 57/218 reads (26%) | catalogued as rs377181911; called by muse, mutect2, varscan2
- RSL1D1 | c.1317G>T p.V439= | Silent (SNP) | VAF 52/107 reads (49%) | called by muse, mutect2, varscan2
- SERPINA2 | c.180C>T p.L60= | Silent (SNP) | VAF 88/174 reads (51%) | catalogued as rs752286655; called by muse, mutect2, varscan2
- SLC39A10 | c.2121C>T p.F707= | Silent (SNP) | VAF 31/62 reads (50%) | called by muse, mutect2, varscan2
- STAB1 | c.5532C>T p.R1844= | Silent (SNP) | VAF 53/186 reads (28%) | catalogued as rs755438496; called by muse, mutect2, varscan2
- TENT5D | c.129C>T p.I43= | Silent (SNP) | VAF 63/217 reads (29%) | catalogued as COSV100382843; called by muse, mutect2, varscan2
- TFAP2E | c.735C>T p.L245= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as rs1308431542; called by muse, mutect2, varscan2
- ZC3H11B | c.303G>A p.V101= | Silent (SNP) | VAF 18/54 reads (33%) | called by mutect2, varscan2
- ZNF768 | c.804G>A p.K268= | Silent (SNP) | VAF 57/135 reads (42%) | called by muse, mutect2, varscan2
- ABCD3 | c.*1441G>A | 3'UTR (SNP) | VAF 17/17 reads (100%) | called by muse, mutect2, varscan2
- ABHD17C | c.*360G>T | 3'UTR (SNP) | VAF 92/133 reads (69%) | called by muse, mutect2, varscan2
- ABTB2 | c.*1004G>A | 3'UTR (SNP) | VAF 85/155 reads (55%) | called by muse, mutect2, varscan2
- ACSS2 | c.*707C>G | 3'UTR (SNP) | VAF 40/80 reads (50%) | called by muse, mutect2, varscan2
- ACTN2 | c.*109G>T | 3'UTR (SNP) | VAF 19/50 reads (38%) | called by muse, mutect2, varscan2
- ADAMTS9 | c.-119T>A | 5'UTR (SNP) | VAF 11/17 reads (65%) | called by muse, mutect2, varscan2
- ADGB | c.4818+1171T>C | Intron (SNP) | VAF 47/85 reads (55%) | called by muse, mutect2, varscan2
- AFF1 | c.*1205C>T | 3'UTR (SNP) | VAF 32/86 reads (37%) | catalogued as COSV57121308; called by muse, mutect2, varscan2
- AHSG | c.-82C>T | 5'UTR (SNP) | VAF 145/484 reads (30%) | catalogued as rs775326907; called by muse, mutect2, varscan2
- AL161729.4 | chr9:95516827 C>T | 3'Flank (SNP) | VAF 35/85 reads (41%) | catalogued as COSV100933540; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.*184G>A | 3'UTR (SNP) | VAF 44/82 reads (54%) | called by muse, mutect2, varscan2
- ANKRD52 | c.*511C>T | 3'UTR (SNP) | VAF 81/192 reads (42%) | called by muse, mutect2, varscan2
- ANOS1 | c.*3104T>G | 3'UTR (SNP) | VAF 15/97 reads (15%) | called by muse, mutect2, varscan2
- AQP4 | c.*481G>A | 3'UTR (SNP) | VAF 11/99 reads (11%) | called by muse, mutect2, varscan2
- ARHGAP29 | c.1282-114G>A | Intron (SNP) | VAF 20/25 reads (80%) | called by mutect2, varscan2
- ARL2BP | c.100+86G>C | Intron (SNP) | VAF 6/28 reads (21%) | called by muse, mutect2
- ASH2L | c.188+119C>T | Intron (SNP) | VAF 8/19 reads (42%) | called by muse, mutect2, varscan2
- ATAD3C | c.-107G>A | 5'UTR (SNP) | VAF 36/88 reads (41%) | called by muse, mutect2, varscan2
- ATP11C | c.-931G>A | 5'UTR (SNP) | VAF 26/257 reads (10%) | called by muse, mutect2
- BCL9L | c.-888G>C | 5'UTR (SNP) | VAF 116/239 reads (49%) | called by muse, mutect2, varscan2
- BDNF | c.-21-748C>T | Intron (SNP) | VAF 31/71 reads (44%) | called by muse, mutect2, varscan2
- BEND2 | c.*311G>A | 3'UTR (SNP) | VAF 16/58 reads (28%) | called by muse, mutect2, varscan2
- BMP6 | c.*600_*601del | 3'UTR (DEL) | VAF 40/124 reads (32%) | called by pindel, varscan2
- BMP6 | c.*1187G>A | 3'UTR (SNP) | VAF 28/54 reads (52%) | catalogued as rs200877924; called by muse, varscan2
- BRWD1 | c.*1648C>T | 3'UTR (SNP) | VAF 11/54 reads (20%) | catalogued as rs1369718301; called by muse, mutect2, varscan2
- BTK | c.*369G>A | 3'UTR (SNP) | VAF 11/135 reads (8%) | called by muse, mutect2
- C10orf143 | c.69+2600G>A | Intron (SNP) | VAF 51/147 reads (35%) | called by muse, mutect2, varscan2
- C4orf33 | c.-406T>C | 5'UTR (SNP) | VAF 6/21 reads (29%) | called by muse, varscan2
- CA5BP1 | n.322-58G>A | Intron (SNP) | VAF 9/31 reads (29%) | called by muse, mutect2
- CACNB4 | c.*5636G>A | 3'UTR (SNP) | VAF 29/60 reads (48%) | called by muse, mutect2, varscan2
- CCDC12 | c.342-19C>G | Intron (SNP) | VAF 14/214 reads (7%) | called by muse, mutect2
- CCDC25 | c.*853G>A | 3'UTR (SNP) | VAF 26/258 reads (10%) | called by muse, mutect2, varscan2
- CCM2L | c.-16G>C | 5'UTR (SNP) | VAF 7/80 reads (9%) | catalogued as rs1357289332; called by muse, mutect2
- CCND3 | c.-38G>A | 5'UTR (SNP) | VAF 5/19 reads (26%) | called by muse, mutect2
- CDH19 | c.*2672G>A | 3'UTR (SNP) | VAF 19/31 reads (61%) | catalogued as rs916942806; called by muse, mutect2, varscan2
- CDKL1 | c.171+17441G>T | Intron (SNP) | VAF 37/93 reads (40%) | catalogued as COSV53579653; called by muse, mutect2, varscan2
- CDKL1 | c.171+17347G>C | Intron (SNP) | VAF 27/65 reads (42%) | called by muse, mutect2, varscan2
- CEP126 | c.-96G>A | 5'UTR (SNP) | VAF 21/40 reads (53%) | catalogued as rs1043438027; called by muse, mutect2, varscan2
- CHD1 | c.*674C>T | 3'UTR (SNP) | VAF 6/14 reads (43%) | called by muse, mutect2, varscan2
- CHKA | c.*648G>A | 3'UTR (SNP) | VAF 5/92 reads (5%) | called by muse, mutect2
- CLLU1 | n.4G>A | RNA (SNP) | VAF 10/20 reads (50%) | catalogued as rs1297363119; called by muse, mutect2, varscan2
- CLN8 | c.*1222C>T | 3'UTR (SNP) | VAF 35/76 reads (46%) | called by muse, mutect2, varscan2
- CNGB3 | c.*1272C>T | 3'UTR (SNP) | VAF 35/87 reads (40%) | called by muse, mutect2, varscan2
- COL10A1 | c.*1058G>A | 3'UTR (SNP) | VAF 4/18 reads (22%) | called by mutect2, varscan2
- COL10A1 | c.*692G>A | 3'UTR (SNP) | VAF 25/56 reads (45%) | called by muse, mutect2, varscan2
- COL10A1 | c.*460G>A | 3'UTR (SNP) | VAF 23/43 reads (53%) | called by muse, mutect2, varscan2
- COL10A1 | c.*360G>C | 3'UTR (SNP) | VAF 21/35 reads (60%) | called by muse, mutect2, varscan2
- COL4A5 | c.*568C>G | 3'UTR (SNP) | VAF 56/82 reads (68%) | called by muse, mutect2, varscan2
- CPS1 | c.*262T>G | 3'UTR (SNP) | VAF 18/52 reads (35%) | called by muse, mutect2, varscan2
- CR1 | c.401+66C>G | Intron (SNP) | VAF 17/57 reads (30%) | called by mutect2, varscan2
- CREB5 | c.*1999dup | 3'UTR (INS) | VAF 16/49 reads (33%) | called by mutect2, varscan2
- CREBRF | c.*1103A>G | 3'UTR (SNP) | VAF 41/92 reads (45%) | called by muse, mutect2, varscan2
- CXCL6 | c.*242G>A | 3'UTR (SNP) | VAF 23/47 reads (49%) | called by muse, mutect2, varscan2
- CYRIB | c.714-148C>T | Intron (SNP) | VAF 7/13 reads (54%) | catalogued as rs1028923733; called by muse, mutect2, varscan2
- CYS1 | c.*1359G>A | 3'UTR (SNP) | VAF 30/74 reads (41%) | called by muse, mutect2
- DEFB118 | c.*622G>T | 3'UTR (SNP) | VAF 12/33 reads (36%) | catalogued as COSV53621355; called by muse, mutect2, varscan2
- DGKZ | c.2938+24C>G | Intron (SNP) | VAF 13/31 reads (42%) | called by muse, mutect2, varscan2
- DHX35 | c.*905G>A | 3'UTR (SNP) | VAF 5/90 reads (6%) | catalogued as rs1404026357; called by muse, mutect2
- DIRAS3 | c.*458G>A | 3'UTR (SNP) | VAF 40/99 reads (40%) | called by muse, mutect2, varscan2
- DOCK4 | c.2109+17G>A | Intron (SNP) | VAF 72/225 reads (32%) | called by muse, mutect2, varscan2
- EEA1 | c.*2292C>T | 3'UTR (SNP) | VAF 22/47 reads (47%) | called by muse, mutect2, varscan2
- EPHA5 | c.3008+252G>T | Intron (SNP) | VAF 36/69 reads (52%) | called by muse, mutect2, varscan2
- ERVFRD-1 | c.*453C>T | 3'UTR (SNP) | VAF 8/129 reads (6%) | called by muse, mutect2
- EXOC6B | c.1980+3321A>C | Intron (SNP) | VAF 34/73 reads (47%) | called by muse, mutect2, varscan2
- FAM20C | c.863+18681G>A | Intron (SNP) | VAF 58/206 reads (28%) | called by muse, mutect2, varscan2
- FAM228A | c.*982C>T | 3'UTR (SNP) | VAF 42/79 reads (53%) | called by muse, mutect2, varscan2
- FAM86C2P | n.920C>T | RNA (SNP) | VAF 22/65 reads (34%) | catalogued as rs775158987; called by muse, mutect2, varscan2
- FBXO48 | c.*1305G>A | 3'UTR (SNP) | VAF 7/56 reads (13%) | called by muse, mutect2, varscan2
- FOXK1 | c.*882G>C | 3'UTR (SNP) | VAF 105/361 reads (29%) | called by mutect2, varscan2
- FOXK1 | c.*5202G>A | 3'UTR (SNP) | VAF 34/106 reads (32%) | called by muse, mutect2, varscan2
- FOXN1 | c.*1360C>T | 3'UTR (SNP) | VAF 54/138 reads (39%) | called by muse, mutect2, varscan2
- GABRA2 | c.187+17689G>C | Intron (SNP) | VAF 24/63 reads (38%) | catalogued as rs1249339662; called by muse, varscan2
- GAREM2 | c.254-1670C>A | Intron (SNP) | VAF 32/83 reads (39%) | called by muse, mutect2, varscan2
- GARNL3 | chr9:127263849 C>G | 5'Flank (SNP) | VAF 5/111 reads (5%) | called by muse, mutect2
- GBP4 | c.*2774C>T | 3'UTR (SNP) | VAF 8/14 reads (57%) | catalogued as rs1392750550; called by mutect2, varscan2
- GDI1 | c.46-77G>C | Intron (SNP) | VAF 18/70 reads (26%) | called by muse, mutect2, varscan2
- GLRA3 | c.*4490T>C | 3'UTR (SNP) | VAF 24/41 reads (59%) | called by mutect2, varscan2
- GLUL | c.*2476G>A | 3'UTR (SNP) | VAF 26/104 reads (25%) | called by muse, mutect2, varscan2
- GON7 | c.*207C>G | 3'UTR (SNP) | VAF 24/70 reads (34%) | called by muse, mutect2, varscan2
- GSX1 | c.*631C>G | 3'UTR (SNP) | VAF 41/98 reads (42%) | called by muse, mutect2, varscan2
- HIP1R | c.-56C>T | 5'UTR (SNP) | VAF 14/33 reads (42%) | catalogued as rs1422857206; called by muse, mutect2, varscan2
- HIPK2 | c.*1757A>C | 3'UTR (SNP) | VAF 45/144 reads (31%) | called by muse, mutect2, varscan2
- HLA-V | n.263G>A | RNA (SNP) | VAF 26/60 reads (43%) | called by muse, varscan2
- HUNK | c.*2379C>T | 3'UTR (SNP) | VAF 45/146 reads (31%) | catalogued as rs765606077; called by muse, mutect2, varscan2
- IGDCC4 | c.422-88C>T | Intron (SNP) | VAF 18/54 reads (33%) | called by muse, mutect2, varscan2
- IGF1R | c.*139G>C | 3'UTR (SNP) | VAF 36/116 reads (31%) | called by muse, mutect2, varscan2
- IGLL5 | c.-46C>A | 5'UTR (SNP) | VAF 42/77 reads (55%) | catalogued as rs536351655, COSV101597140; called by muse, mutect2, varscan2
- KCNE5 | c.*36C>T | 3'UTR (SNP) | VAF 16/45 reads (36%) | called by muse, mutect2, varscan2
- KIAA1614 | c.*2500G>C | 3'UTR (SNP) | VAF 35/86 reads (41%) | called by muse, mutect2, varscan2
- KPNA1 | c.*1794C>G | 3'UTR (SNP) | VAF 33/126 reads (26%) | catalogued as COSV100724229; called by muse, mutect2, varscan2
- KRT15 | chr17:41521714 C>A | 5'Flank (SNP) | VAF 12/156 reads (8%) | called by muse, mutect2
- LCE2B | c.*174T>G | 3'UTR (SNP) | VAF 32/88 reads (36%) | catalogued as COSV100909329; called by muse, mutect2, varscan2
- LINC00993 | n.315-4324G>A | Intron (SNP) | VAF 26/53 reads (49%) | called by muse, mutect2, varscan2
- LINC01620 | n.395+28C>G | Intron (SNP) | VAF 39/88 reads (44%) | called by muse, mutect2, varscan2
- LRRC55 | c.*1411G>A | 3'UTR (SNP) | VAF 6/93 reads (6%) | catalogued as rs1053148488; called by muse, mutect2
- LRTM2 | c.*1586C>T | 3'UTR (SNP) | VAF 70/170 reads (41%) | catalogued as rs962562371; called by muse, mutect2
- LTBP2 | c.*1889C>T | 3'UTR (SNP) | VAF 41/83 reads (49%) | called by muse, mutect2, varscan2
- LTBP2 | c.*1647C>G | 3'UTR (SNP) | VAF 24/44 reads (55%) | called by muse, mutect2, varscan2
- MAF | c.*771A>G | 3'UTR (SNP) | VAF 49/107 reads (46%) | called by muse, mutect2, varscan2
- MAF | c.*169A>T | 3'UTR (SNP) | VAF 7/27 reads (26%) | called by muse, mutect2, varscan2
- MAF | c.*4T>G | 3'UTR (SNP) | VAF 88/321 reads (27%) | called by muse, mutect2, varscan2
- MAF | c.-67C>T | 5'UTR (SNP) | VAF 9/24 reads (38%) | called by muse, varscan2
- MAF | c.-742C>G | 5'UTR (SNP) | VAF 26/74 reads (35%) | called by muse, mutect2, varscan2
- MAP3K11 | c.*331G>C | 3'UTR (SNP) | VAF 9/120 reads (8%) | called by muse, mutect2
- MBNL3 | chrX:132374683 C>G | 3'Flank (SNP) | VAF 79/102 reads (77%) | called by muse, mutect2, varscan2
- MDM2 | c.*2202C>T | 3'UTR (SNP) | VAF 13/321 reads (4%) | called by muse, mutect2
- MEIOC | c.2457+678C>T | Intron (SNP) | VAF 10/16 reads (63%) | called by muse, mutect2, varscan2
- MICAL1 | c.1856-93G>C | Intron (SNP) | VAF 11/23 reads (48%) | called by muse, mutect2, varscan2
- MKS1 | c.516-16C>T | Intron (SNP) | VAF 4/12 reads (33%) | called by mutect2, varscan2
- MMP8 | chr11:102724975 C>T | 5'Flank (SNP) | VAF 85/237 reads (36%) | called by muse, mutect2
- MRGPRX1 | c.-138C>T | 5'UTR (SNP) | VAF 74/261 reads (28%) | called by muse, mutect2, varscan2
- MRPL37 | chr1:54220711 C>A | 3'Flank (SNP) | VAF 77/177 reads (44%) | called by muse, mutect2, varscan2
- MSRB3 | c.*2690G>A | 3'UTR (SNP) | VAF 37/81 reads (46%) | called by muse, mutect2, varscan2
- MTMR1 | c.*8+54C>T | Intron (SNP) | VAF 40/125 reads (32%) | called by muse, mutect2, varscan2
- MXD3 | c.*24C>T | 3'UTR (SNP) | VAF 66/143 reads (46%) | called by muse, mutect2, varscan2
- NEBL | c.*3839C>T | 3'UTR (SNP) | VAF 52/96 reads (54%) | called by muse, mutect2, varscan2
- NFASC | c.*549C>T | 3'UTR (SNP) | VAF 44/155 reads (28%) | called by muse, mutect2, varscan2
- NLGN1 | c.*1555G>A | 3'UTR (SNP) | VAF 35/111 reads (32%) | catalogued as rs917140399; called by muse, mutect2, varscan2
- NLN | c.*3583G>A | 3'UTR (SNP) | VAF 24/61 reads (39%) | catalogued as rs553232766; called by muse, mutect2, varscan2
- NOS1AP | c.940-768C>T | Intron (SNP) | VAF 46/169 reads (27%) | called by muse, mutect2, varscan2
- OTULIN | c.*2742G>A | 3'UTR (SNP) | VAF 28/52 reads (54%) | catalogued as rs959236878; called by muse, mutect2, varscan2
- PAQR8 | c.*1156G>C | 3'UTR (SNP) | VAF 48/116 reads (41%) | called by muse, mutect2, varscan2
- PCDH8 | c.*424G>A | 3'UTR (SNP) | VAF 26/69 reads (38%) | called by muse, mutect2, varscan2
- PCDHB6 | chr5:141156816 del C | 3'Flank (DEL) | VAF 22/73 reads (30%) | called by mutect2, pindel, varscan2
- PDPR | c.1472-57A>G | Intron (SNP) | VAF 88/186 reads (47%) | catalogued as COSV55355686; called by muse, varscan2
- PEDS1-UBE2V1 | c.121+2236A>T | Intron (SNP) | VAF 5/99 reads (5%) | called by muse, mutect2
- PEDS1-UBE2V1 | c.121+2234G>C | Intron (SNP) | VAF 6/100 reads (6%) | catalogued as COSV59016239; called by muse, mutect2
- PHC2 | c.2423-981C>T | Intron (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2, varscan2
- POU2F1 | c.*5573G>A | 3'UTR (SNP) | VAF 14/58 reads (24%) | called by muse, mutect2, varscan2
- PPP1R37 | c.1296+15G>C | Intron (SNP) | VAF 63/228 reads (28%) | called by muse, mutect2, varscan2
- PREX1 | c.*891T>A | 3'UTR (SNP) | VAF 22/53 reads (42%) | called by muse, mutect2, varscan2
- PRRT2 | c.*306G>A | 3'UTR (SNP) | VAF 122/257 reads (47%) | called by muse, mutect2, varscan2
- PRRX2 | c.*90G>A | 3'UTR (SNP) | VAF 52/106 reads (49%) | called by muse, mutect2, varscan2
- PTPN1 | c.*1879C>A | 3'UTR (SNP) | VAF 6/12 reads (50%) | called by muse, mutect2, varscan2
- PTPRC | c.100+1902C>T | Intron (SNP) | VAF 38/125 reads (30%) | called by muse, mutect2, varscan2
- PTPRN2 | c.2344+4466C>A | Intron (SNP) | VAF 55/94 reads (59%) | called by muse, mutect2, varscan2
- PTS | chr11:112226410 G>A | 5'Flank (SNP) | VAF 17/33 reads (52%) | called by muse, mutect2, varscan2
- PXDN | c.4207-13T>G | Intron (SNP) | VAF 7/73 reads (10%) | called by muse, mutect2, varscan2
- PYGO1 | c.*4651G>A | 3'UTR (SNP) | VAF 20/73 reads (27%) | called by muse, mutect2, varscan2
- RAB27B | c.*5754G>A | 3'UTR (SNP) | VAF 23/44 reads (52%) | catalogued as rs1021488599; called by muse, mutect2, varscan2
- RASGEF1A | chr10:43195635 G>A | 3'Flank (SNP) | VAF 32/88 reads (36%) | called by muse, mutect2, varscan2
- RBM4 | c.*155C>T | 3'UTR (SNP) | VAF 48/89 reads (54%) | catalogued as rs946096847; called by muse, mutect2, varscan2
- RC3H1 | c.*4863C>T | 3'UTR (SNP) | VAF 40/114 reads (35%) | called by muse, mutect2, varscan2
- RDH11 | c.*845G>A | 3'UTR (SNP) | VAF 13/30 reads (43%) | called by muse, mutect2, varscan2
- REPS1 | c.*981A>C | 3'UTR (SNP) | VAF 40/96 reads (42%) | called by muse, mutect2, varscan2
- RGP1 | c.*4865G>A | 3'UTR (SNP) | VAF 38/92 reads (41%) | called by muse, mutect2, varscan2
- RHOBTB3 | c.3-27C>T | Intron (SNP) | VAF 27/55 reads (49%) | catalogued as rs950003255; called by muse, mutect2, varscan2
- RNF217 | c.*555G>A | 3'UTR (SNP) | VAF 30/66 reads (45%) | called by muse, mutect2, varscan2
- RNF217-AS1 | n.3644T>G | RNA (SNP) | VAF 11/21 reads (52%) | called by muse, mutect2, varscan2
- RORA | c.*1032G>A | 3'UTR (SNP) | VAF 35/111 reads (32%) | catalogued as rs995481341; called by muse, mutect2, varscan2
- RPE | c.*375C>T | 3'UTR (SNP) | VAF 11/29 reads (38%) | called by muse, mutect2, varscan2
- RPL10 | c.330-162G>C | Intron (SNP) | VAF 10/50 reads (20%) | called by muse, mutect2
- RSBN1 | c.*2545G>A | 3'UTR (SNP) | VAF 26/80 reads (33%) | called by muse, mutect2, varscan2
- RSPH14 | c.421+2390G>A | Intron (SNP) | VAF 93/199 reads (47%) | called by muse, mutect2, varscan2
- RSPH9 | c.*256G>A | 3'UTR (SNP) | VAF 47/92 reads (51%) | called by muse, mutect2, varscan2
- S100A14 | c.*435C>T | 3'UTR (SNP) | VAF 48/163 reads (29%) | called by muse, mutect2, varscan2
- SELENOI | c.*2234C>G | 3'UTR (SNP) | VAF 53/98 reads (54%) | catalogued as rs1213651990; called by muse, varscan2
- SIPA1L3 | c.*538G>A | 3'UTR (SNP) | VAF 11/321 reads (3%) | called by muse, mutect2
- SLC25A36 | c.385+1917G>A | Intron (SNP) | VAF 25/79 reads (32%) | called by muse, mutect2, varscan2
- SLC37A1 | c.982-174C>T | Intron (SNP) | VAF 10/40 reads (25%) | called by muse, mutect2
- SLIT1 | c.*2215G>C | 3'UTR (SNP) | VAF 40/97 reads (41%) | called by muse, mutect2, varscan2
- SPDYE4 | c.-28G>C | 5'UTR (SNP) | VAF 59/135 reads (44%) | called by muse, mutect2, varscan2
- SPICE1 | c.-1+421G>A | Intron (SNP) | VAF 9/27 reads (33%) | catalogued as rs1159920368; called by mutect2, varscan2
- SPRED1 | c.*153C>T | 3'UTR (SNP) | VAF 22/68 reads (32%) | called by muse, mutect2, varscan2
- SSBL3P1 | n.769C>T | RNA (SNP) | VAF 29/88 reads (33%) | catalogued as rs1314074512; called by muse, mutect2, varscan2
- ST8SIA5 | c.-129C>T | 5'UTR (SNP) | VAF 23/42 reads (55%) | called by muse, mutect2, varscan2
- STIP1 | chr11:64185804 C>G | 5'Flank (SNP) | VAF 125/254 reads (49%) | called by muse, mutect2, varscan2
- STOX2 | c.-32G>A | 5'UTR (SNP) | VAF 49/105 reads (47%) | called by muse, mutect2, varscan2
- SYNCRIP | chr6:85610929 G>A | 3'Flank (SNP) | VAF 62/125 reads (50%) | called by muse, mutect2, varscan2
- TAFA5 | c.*1614G>T | 3'UTR (SNP) | VAF 52/120 reads (43%) | called by muse, varscan2
- TEAD1 | c.*6050C>G | 3'UTR (SNP) | VAF 24/61 reads (39%) | called by muse, mutect2, varscan2
- TFEC | c.*1080C>T | 3'UTR (SNP) | VAF 15/44 reads (34%) | called by muse, mutect2, varscan2
- TGIF1 | c.-624C>A | 5'UTR (SNP) | VAF 58/118 reads (49%) | called by muse, mutect2, varscan2
- THUMPD2 | c.673-388G>T | Intron (SNP) | VAF 12/39 reads (31%) | called by muse, mutect2
- TIFAB | c.*274G>A | 3'UTR (SNP) | VAF 33/57 reads (58%) | catalogued as rs867527490; called by muse, mutect2, varscan2
- TIMP3 | c.-174C>T | 5'UTR (SNP) | VAF 12/19 reads (63%) | called by muse, mutect2, varscan2
- TMEM106B | c.*2377G>C | 3'UTR (SNP) | VAF 10/39 reads (26%) | called by muse, mutect2, varscan2
- TMEM164 | c.*1752G>A | 3'UTR (SNP) | VAF 52/125 reads (42%) | called by muse, mutect2, varscan2
- TMEM199 | c.*1391G>T | 3'UTR (SNP) | VAF 7/13 reads (54%) | called by muse, mutect2, varscan2
- TNFRSF1B | c.*158C>G | 3'UTR (SNP) | VAF 60/112 reads (54%) | called by muse, mutect2, varscan2
- TNFRSF1B | c.*402C>G | 3'UTR (SNP) | VAF 30/59 reads (51%) | catalogued as rs1171904965; called by muse, varscan2
- TPP2 | c.-19C>T | 5'UTR (SNP) | VAF 37/71 reads (52%) | catalogued as COSV65751519; called by muse, mutect2, varscan2
- TRIM6 | c.*1170G>C | 3'UTR (SNP) | VAF 15/40 reads (38%) | called by muse, mutect2, varscan2
- TRMT61A | c.*1706C>T | 3'UTR (SNP) | VAF 71/153 reads (46%) | called by muse, mutect2, varscan2
- TRNAU1AP | chr1:28579938 T>A | 3'Flank (SNP) | VAF 43/86 reads (50%) | called by muse, mutect2, varscan2
- TSPYL5 | c.*2360T>A | 3'UTR (SNP) | VAF 16/31 reads (52%) | catalogued as rs538781254, COSV59072139; called by mutect2, varscan2
- TTLL3 | c.1547+25C>T | Intron (SNP) | VAF 29/99 reads (29%) | catalogued as rs774887974; called by muse, mutect2, varscan2
- UBR7 | c.*1913C>T | 3'UTR (SNP) | VAF 7/94 reads (7%) | called by muse, mutect2
- USP25 | c.780+54T>C | Intron (SNP) | VAF 8/43 reads (19%) | called by muse, mutect2
- VGLL3 | c.*2374A>C | 3'UTR (SNP) | VAF 62/91 reads (68%) | called by muse, mutect2, varscan2
- VPS13A | c.6378+305C>T | Intron (SNP) | VAF 10/29 reads (34%) | called by muse, mutect2, varscan2
- VPS36 | c.906-23G>T | Intron (SNP) | VAF 29/65 reads (45%) | called by muse, mutect2, varscan2
- VPS45 | chr1:150067573 G>A | 5'Flank (SNP) | VAF 75/251 reads (30%) | called by muse, varscan2
- Y_RNA | chr3:48286874 G>C | 5'Flank (SNP) | VAF 55/200 reads (28%) | called by muse, varscan2
- ZBTB44 | c.*1734G>C | 3'UTR (SNP) | VAF 26/69 reads (38%) | called by muse, mutect2, varscan2
- ZNF250 | c.*2517G>T | 3'UTR (SNP) | VAF 45/103 reads (44%) | called by muse, mutect2, varscan2
- ZNF48 | c.*44G>T | 3'UTR (SNP) | VAF 26/55 reads (47%) | catalogued as rs1207582330; called by muse, mutect2, varscan2
- ZNF606 | chr19:58005052 G>A | 5'Flank (SNP) | VAF 14/45 reads (31%) | called by muse, mutect2, varscan2
- ZNF74 | c.34+117dup | Intron (INS) | VAF 7/48 reads (15%) | catalogued as rs3072071; called by pindel, varscan2*
- ZNF812P | n.436C>T | RNA (SNP) | VAF 119/352 reads (34%) | called by muse, mutect2, varscan2
- ZNRF2 | c.-293G>A | 5'UTR (SNP) | VAF 16/33 reads (48%) | called by muse, mutect2, varscan2
